Somatic mutation profile of tumor specimen ALCH-B1P8-TTP1-A (aliquot ALCH-B1P8-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1P8, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.5 years (20,265 days).
Specimen ALCH-B1P8-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29ffa4c6-22db-48db-984f-4e2b2c206f3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1P8-NB1-A (Blood Derived Normal), aliquot ALCH-B1P8-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/729b0c38-4526-4ef9-86e0-6b74e709b75e

The open-access MAF lists 411 somatic variants for this specimen: 274 protein-altering or splice-affecting, 86 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 236, Silent 86, Intron 26, Nonsense Mutation 15, RNA 13, Frame Shift Del 11, Splice Site 6, 5'Flank 5, 3'UTR 4, Splice Region 4, 5'UTR 3, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL1A1 | c.3123del p.A1042Lfs*66 | Frame Shift Del (DEL) | VAF 43/374 reads (11%) | catalogued as rs886039693; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 105/358 reads (29%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 90/436 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAR2 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.562); catalogued as rs1387932119; called by muse, mutect2, varscan2
- ABCA3 | c.2141G>T p.R714L | Missense Mutation (SNP) | VAF 132/745 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57056330; called by muse, mutect2, varscan2
- ABCB1 | c.1542G>T p.M514I | Missense Mutation (SNP) | VAF 35/560 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV55964706; called by muse, mutect2
- ACSM2B | c.1098G>T p.T366= | Splice Region (SNP) | VAF 37/210 reads (18%) | catalogued as COSV61657196; called by muse, mutect2, varscan2
- AGT | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 47/473 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs748047212; called by muse, mutect2
- AK9 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs1277011072; called by muse, mutect2, varscan2
- AL645922.1 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 24/758 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as rs1464680465, COSV54960803; called by muse, mutect2
- AMER3 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.813); catalogued as COSV100366741; called by muse, mutect2, varscan2
- AMZ1 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 31/360 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56687918; called by muse, mutect2
- ANO5 | c.469G>T p.D157Y | Missense Mutation (SNP) | VAF 52/358 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100201959; called by muse, mutect2, varscan2
- APOB | c.7424C>G p.A2475G | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV99267747; called by muse, mutect2, varscan2
- ATL1 | c.1429T>C p.C477R | Missense Mutation (SNP) | VAF 30/393 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as rs751845423; called by muse, mutect2
- BACE2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 44/341 reads (13%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.946); catalogued as rs549639705, COSV100161293; called by muse, mutect2, varscan2
- C4orf50 | c.370G>T p.E124* (on ENST00000324058; = p.E1356* on NM_001364689.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/175 reads (18%) | catalogued as COSV60687495; called by muse, mutect2, varscan2
- CACNA2D4 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 106/328 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99765272; called by muse, mutect2, varscan2
- CDH10 | c.668C>A p.P223Q | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.704); catalogued as COSV100049804, COSV52604817; called by muse, varscan2
- CDH8 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 38/441 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766629695, COSV54858441, COSV99076733; called by muse, mutect2
- CFAP61 | c.2572G>A p.V858M | Missense Mutation (SNP) | VAF 68/387 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.134); catalogued as rs775929345, COSV99844962; called by muse, mutect2, varscan2
- CNTNAP2 | c.467C>G p.A156G | Missense Mutation (SNP) | VAF 38/460 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV62163155; called by muse, mutect2
- CNTNAP2 | c.1694A>G p.H565R | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757944719; called by muse, mutect2, varscan2
- CNTNAP4 | c.1548G>A p.M516I | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV56703385; called by muse, mutect2, varscan2
- CSMD3 | c.9862C>G p.P3288A (on ENST00000297405 / NM_001363185.1; = p.P3119A on NM_052900.3) | Missense Mutation (SNP) | VAF 45/301 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); catalogued as COSV99823123; called by muse, mutect2, varscan2
- CSMD3 | c.6853G>T p.G2285W (on ENST00000297405 / NM_001363185.1; = p.G2181W on NM_052900.3) | Missense Mutation (SNP) | VAF 49/416 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52155821; called by muse, mutect2, varscan2
- CWH43 | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99893578, COSV99894338; called by muse, mutect2, varscan2
- DACH1 | c.1261C>T p.Q421* | Nonsense Mutation (SNP) | VAF 31/232 reads (13%) | catalogued as rs922296793; called by muse, mutect2, varscan2
- DCAF4L2 | c.227G>T p.R76L | Missense Mutation (SNP) | VAF 155/804 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs865992251, COSV60477474, COSV60477956; called by muse, mutect2, varscan2
- DCHS1 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 38/294 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs374740842, COSV100201706; called by muse, mutect2, varscan2
- DNAH7 | c.9426-1G>T p.X3142_splice | Splice Site (SNP) | VAF 6/51 reads (12%) | catalogued as COSV56781651; called by muse, mutect2, varscan2
- ERMP1 | c.2173C>T p.H725Y | Missense Mutation (SNP) | VAF 67/394 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs1455080367; called by muse, mutect2, varscan2
- FAM135B | c.1559C>A p.T520N | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV52716443; called by muse, mutect2, varscan2
- FAM13A | c.3068T>C p.M1023T | Missense Mutation (SNP) | VAF 52/319 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1441074481; called by muse, mutect2, varscan2
- FAM83B | c.1377G>T p.R459S | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60921971, COSV60925896; called by muse, mutect2, varscan2
- FAT3 | c.7271C>A p.S2424Y | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV53181989; called by muse, mutect2, varscan2
- FCER1A | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 59/597 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.218); catalogued as COSV63667036; called by muse, mutect2
- FLG | c.7459del p.H2487Tfs*113 | Frame Shift Del (DEL) | VAF 72/581 reads (12%) | catalogued as COSV104425352; called by mutect2, pindel, varscan2
- FLT3 | c.2789C>T p.S930L | Missense Mutation (SNP) | VAF 59/279 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as rs1280498093, COSV54048994; called by muse, mutect2, varscan2
- GALNT17 | c.1612C>T p.L538F | Missense Mutation (SNP) | VAF 15/405 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100356550; called by muse, mutect2
- GRIA1 | c.947G>T p.R316L | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.397); catalogued as rs768979604; called by muse, mutect2, varscan2
- HMX1 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.438); catalogued as rs577238615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HTR2C | c.750C>A p.H250Q | Missense Mutation (SNP) | VAF 35/283 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52203838, COSV52221497; called by muse, mutect2, varscan2
- HTT | c.8651G>A p.R2884H | Missense Mutation (SNP) | VAF 55/641 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1193396566; called by muse, mutect2
- IGHV2-26 | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 143/637 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781944690; called by muse, mutect2, varscan2
- ITSN2 | c.4574G>A p.R1525Q | Missense Mutation (SNP) | VAF 58/348 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs542519689, COSV61951412; called by muse, mutect2, varscan2
- KCMF1 | c.1032G>A p.M344I | Missense Mutation (SNP) | VAF 83/555 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs923461364, COSV69054493; called by muse, mutect2, varscan2
- KCND2 | c.799G>T p.V267L | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.556); catalogued as COSV58582117; called by muse, mutect2
- KCNH5 | c.1569G>C p.K523N | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV59751854; called by muse, mutect2
- KEAP1 | c.1490G>T p.W497L | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV50276071; called by muse, mutect2, varscan2
- KHSRP | c.2089G>T p.G697C | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV67919546; called by muse, mutect2, varscan2
- LRP1B | c.1004C>G p.P335R | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV101255697; called by muse, mutect2, varscan2
- LYST | c.7060-1G>T p.X2354_splice | Splice Site (SNP) | VAF 12/158 reads (8%) | catalogued as CS1110854, CS1110855; called by muse, mutect2
- MBL2 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 89/591 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV64758656; called by muse, mutect2, varscan2
- MEGF10 | c.1045C>A p.R349S | Missense Mutation (SNP) | VAF 127/643 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV57245326, COSV99175084; called by muse, mutect2, varscan2
- MEGF8 | c.5759G>T p.R1920L (on ENST00000251268 / NM_001271938.2; = p.R1853L on NM_001410.3) | Missense Mutation (SNP) | VAF 38/246 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.04); catalogued as COSV52085812; called by muse, mutect2, varscan2
- MEI1 | c.794del p.G265Dfs*41 | Frame Shift Del (DEL) | VAF 32/267 reads (12%) | catalogued as COSV100299863; called by mutect2, pindel, varscan2
- MOXD1 | c.1480G>T p.G494W | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100381459; called by muse, mutect2, varscan2
- MPO | c.902C>A p.P301H | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1191500981; called by muse, mutect2, varscan2
- MYO3A | c.4418C>A p.S1473Y | Missense Mutation (SNP) | VAF 72/770 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.401); catalogued as COSV56340251; called by muse, mutect2
- MYO3B | c.850G>T p.V284F | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV58692949; called by muse, mutect2, varscan2
- MYPN | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 85/502 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.042); catalogued as rs200352249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NETO1 | c.532G>T p.G178C | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55002002, COSV55014561; called by muse, mutect2, varscan2
- NLRP5 | c.3445C>T p.P1149S | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.764); catalogued as rs574103124, COSV66765749; called by muse, mutect2, varscan2
- NOD2 | c.1534G>C p.D512H | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1212673; called by muse, mutect2
- NUAK1 | c.661C>A p.P221T | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54602841; called by muse, mutect2, varscan2
- OR14C36 | c.410del p.R137Qfs*6 | Frame Shift Del (DEL) | VAF 17/198 reads (9%) | catalogued as COSV58602253, COSV58602467; called by mutect2, pindel
- OR2H1 | c.166C>G p.P56A | Missense Mutation (SNP) | VAF 76/557 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as rs773435222; called by muse, mutect2, varscan2
- OR2M2 | c.74C>A p.T25K | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.683); catalogued as rs146796261, COSV100677211; called by muse, mutect2, varscan2
- OR4Q3 | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 28/264 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59178476, COSV59180133; called by muse, mutect2, varscan2
- OR51A4 | c.95C>A p.P32H | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66749295; called by muse, varscan2
- OR5H14 | c.602T>C p.I201T | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs774046022; called by muse, mutect2, varscan2
- OR6F1 | c.752G>T p.W251L | Missense Mutation (SNP) | VAF 31/301 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as COSV100129389; called by muse, mutect2, varscan2
- P4HA1 | c.1084C>G p.R362G | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs201944122; called by muse, mutect2
- PAPPA | c.3260G>T p.R1087L | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs200046193, COSV100073020; called by muse, mutect2, varscan2
- PIGZ | c.455G>T p.G152V | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as rs984311974; called by muse, mutect2, varscan2
- PLCB4 | c.665T>C p.I222T | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs757589036; called by muse, mutect2, varscan2
- PLEC | c.5285A>G p.E1762G (on ENST00000322810 / NM_201380.4; = p.E1652G on NM_000445.5) | Missense Mutation (SNP) | VAF 45/487 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as rs1480796001; called by muse, mutect2
- PNLIPRP2 | c.1245G>T p.Q415H (on ENST00000611850; = p.Q416H on NM_005396.5) | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.05); catalogued as rs782132023; called by muse, mutect2, varscan2
- POTEF | c.2159G>A p.G720D | Missense Mutation (SNP) | VAF 110/1077 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.316); catalogued as rs571977776; called by muse, mutect2
- PRR12 | c.221G>A p.G74E (on ENST00000615927; = p.G895E on NM_020719.3) | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.026); catalogued as rs770934345; called by muse, mutect2, varscan2
- PRR23C | c.38C>A p.A13E | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.039); catalogued as rs1457133253; called by muse, mutect2, varscan2
- PRR35 | c.936G>T p.W312C | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV99552282; called by muse, mutect2
- PSG9 | c.1251C>A p.C417* | Nonsense Mutation (SNP) | VAF 29/172 reads (17%) | catalogued as rs768602738; called by muse, mutect2, varscan2
- RALGAPA2 | c.4849del p.D1617Tfs*9 | Frame Shift Del (DEL) | VAF 18/105 reads (17%) | catalogued as COSV99173054; called by mutect2, pindel, varscan2
- REG3G | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 32/261 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751828914, COSV55449435; called by muse, mutect2, varscan2
- RGS22 | c.817G>T p.G273* | Nonsense Mutation (SNP) | VAF 6/63 reads (10%) | catalogued as rs996389665; called by mutect2, varscan2
- RTL3 | c.1111del p.D371Mfs*31 | Frame Shift Del (DEL) | VAF 68/541 reads (13%) | catalogued as COSV100330198; called by mutect2, pindel, varscan2
- RYR2 | c.8806G>A p.A2936T | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.267); catalogued as rs746339261; called by muse, mutect2
- SAMD9L | c.3785C>T p.S1262L | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100560405; called by muse, mutect2, varscan2
- SBDS | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 97/695 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55887485; called by muse, mutect2, varscan2
- SCN1A | c.4168G>T p.V1390L (on ENST00000303395 / NM_001202435.3; = p.V1379L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/289 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as CM024307, CM115993, COSV57666805; called by muse, mutect2, varscan2
- SEMA3A | c.1451G>T p.R484L | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV99548121; called by muse, mutect2, varscan2
- SIK3 | c.3362C>T p.P1121L (on ENST00000445177 / NM_001366686.2; = p.P1079L on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.013); catalogued as rs768490309; called by muse, mutect2, varscan2
- SORL1 | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 36/264 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.121); catalogued as rs1225171811, COSV52752500; called by muse, mutect2, varscan2
- SPIDR | c.1181C>G p.S394* | Nonsense Mutation (SNP) | VAF 39/415 reads (9%) | catalogued as COSV52390712; called by muse, mutect2
- SPTA1 | c.6997T>A p.Y2333N | Missense Mutation (SNP) | VAF 57/440 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as COSV63749233; called by muse, mutect2, varscan2
- TELO2 | c.1961G>T p.G654V | Missense Mutation (SNP) | VAF 63/405 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1347447311; called by muse, mutect2, varscan2
- TIAM1 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 86/763 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs780427376; called by muse, mutect2, varscan2
- TMPO | c.1292A>G p.Y431C | Missense Mutation (SNP) | VAF 103/300 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1348130942; called by muse, mutect2, varscan2
- TRPC7 | c.1507G>A p.V503M | Missense Mutation (SNP) | VAF 42/536 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.418); catalogued as rs371141920; called by muse, mutect2
- TTBK1 | c.3245G>A p.R1082Q | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs776032948; called by muse, mutect2, varscan2
- WFIKKN2 | c.1646C>T p.S549L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.118); catalogued as rs775664209, COSV60959646; called by muse, mutect2, varscan2
- ZFHX4 | c.6965C>A p.P2322H | Missense Mutation (SNP) | VAF 64/412 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV50571317; called by muse, mutect2, varscan2
- ZNF521 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV64127965; called by muse, mutect2, varscan2
- ZNF676 | c.1438C>A p.P480T (on ENST00000650058; = p.P448T on NM_001001411.3) | Missense Mutation (SNP) | VAF 69/453 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs577032511, COSV68094949; called by muse, mutect2, varscan2
- ZNF718 | c.584G>C p.G195A | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.874); catalogued as COSV101210222; called by mutect2, varscan2
- ZNF91 | c.2578G>C p.G860R | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768194895; called by muse, mutect2, varscan2
- AATK | c.1565A>T p.H522L (on ENST00000326724 / NM_001080395.3; = p.H419L on NM_004920.2) | Missense Mutation (SNP) | VAF 35/280 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- ACTN1 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 113/580 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- ADAMTSL3 | c.2371A>T p.T791S | Missense Mutation (SNP) | VAF 27/315 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.622); called by muse, mutect2
- ADAMTSL3 | c.4918del p.Q1640Rfs*30 | Frame Shift Del (DEL) | VAF 51/503 reads (10%) | called by mutect2, pindel, varscan2
- AGBL1 | c.2296C>A p.L766M | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- AIFM3 | c.1462A>T p.M488L | Missense Mutation (SNP) | VAF 290/541 reads (54%) | SIFT tolerated (0.16); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AKAP9 | c.7732G>C p.A2578P (on ENST00000359028; = p.A2554P on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/511 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AL645922.1 | c.3301T>C p.C1101R | Missense Mutation (SNP) | VAF 132/952 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARPP21 | c.2026C>A p.Q676K | Missense Mutation (SNP) | VAF 41/209 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ATP10A | c.3934A>T p.R1312W | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- AVEN | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- B3GAT2 | c.329A>G p.Q110R | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BCL11B | c.2321G>T p.G774V (on ENST00000357195 / NM_001282237.2; = p.G703V on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- BPIFA1 | c.629T>A p.I210N | Missense Mutation (SNP) | VAF 48/428 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- C11orf87 | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 68/557 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1QTNF7 | c.55del p.R19Gfs*5 | Frame Shift Del (DEL) | VAF 82/553 reads (15%) | called by mutect2, pindel, varscan2
- C1orf167 | c.3191G>A p.W1064* | Nonsense Mutation (SNP) | VAF 16/132 reads (12%) | called by muse, mutect2, varscan2
- CACNB3 | c.1324C>A p.Q442K | Missense Mutation (SNP) | VAF 251/799 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CADPS2 | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAGE1 | c.2305T>A p.F769I (on ENST00000512086; = p.F633I on NM_205864.3) | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCNY | c.651A>T p.L217F | Missense Mutation (SNP) | VAF 68/424 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CD1E | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CD248 | c.1390C>A p.H464N | Missense Mutation (SNP) | VAF 34/195 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.107); called by muse, mutect2
- CD8A | c.24G>T p.L8F | Missense Mutation (SNP) | VAF 51/349 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CDKN2A | c.378_420del p.A127Tfs*5 | Frame Shift Del (DEL) | VAF 118/612 reads (19%) | called by mutect2, pindel
- CDON | c.1198+1G>T p.X400_splice | Splice Site (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2, varscan2
- CDON | c.1198G>T p.D400Y | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- CLSTN3 | c.1478G>T p.C493F | Missense Mutation (SNP) | VAF 142/510 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CMYA5 | c.11034G>T p.M3678I | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CPNE3 | c.1369G>T p.G457* | Nonsense Mutation (SNP) | VAF 123/581 reads (21%) | called by muse, mutect2, varscan2
- CR1 | c.961G>C p.E321Q (on ENST00000367051; = p.E771Q on NM_000651.6) | Missense Mutation (SNP) | VAF 65/664 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CSF1R | c.654G>T p.E218D | Missense Mutation (SNP) | VAF 94/464 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CWC22 | c.1546A>T p.M516L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DAB1 | c.1157C>A p.P386H (on ENST00000371231; = p.P353H on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/296 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); called by muse, mutect2
- DACH1 | c.1792G>T p.G598* (on ENST00000619232 / NM_001366712.1; = p.G344* on NM_004392.6) | Nonsense Mutation (SNP) | VAF 44/288 reads (15%) | called by muse, mutect2
- DACH1 | c.1790A>T p.H597L (on ENST00000619232 / NM_001366712.1; = p.H343L on NM_004392.6) | Missense Mutation (SNP) | VAF 44/292 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.921); called by muse, mutect2
- DDC | c.315+6G>T | Splice Region (SNP) | VAF 46/585 reads (8%) | called by muse, mutect2
- DDI1 | c.239T>C p.V80A | Missense Mutation (SNP) | VAF 52/527 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DENND2A | c.284C>A p.A95D | Missense Mutation (SNP) | VAF 40/471 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, mutect2
- DGKZ | c.116A>G p.Q39R | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- DLG2 | c.1181+2T>C p.X394_splice | Splice Site (SNP) | VAF 19/101 reads (19%) | called by muse, varscan2
- DNHD1 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 59/351 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DYNC1I1 | c.1760C>A p.A587D | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.071); called by muse, mutect2
- DYNC2H1 | c.8158C>A p.P2720T | Missense Mutation (SNP) | VAF 41/332 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- DYSF | c.2909A>T p.D970V | Missense Mutation (SNP) | VAF 94/632 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- EIF4E3 | c.345-1G>C p.X115_splice (on ENST00000425534 / NM_001134651.2; = p.X9_splice on NM_173359.5) | Splice Site (SNP) | VAF 42/232 reads (18%) | called by muse, mutect2, varscan2
- ELOA3D | c.1019A>T p.Q340L | Missense Mutation (SNP) | VAF 98/2815 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.307); called by muse, mutect2
- EOMES | c.1667A>T p.Q556L | Missense Mutation (SNP) | VAF 90/368 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- FAM181B | c.398G>T p.S133I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2
- FBXO31 | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2
- FCRL2 | c.251C>G p.T84S | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FIBIN | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 11/80 reads (14%) | called by muse, mutect2, varscan2
- G3BP2 | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 121/839 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GATA2 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GATA5 | c.787G>T p.V263L | Missense Mutation (SNP) | VAF 61/300 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDF10 | c.1150G>C p.D384H | Missense Mutation (SNP) | VAF 48/362 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPA33 | c.506C>A p.P169Q | Missense Mutation (SNP) | VAF 25/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- GPR17 | c.419A>T p.Y140F | Missense Mutation (SNP) | VAF 56/306 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIA2 | c.2273C>A p.P758H | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM5 | c.328A>T p.I110F | Missense Mutation (SNP) | VAF 74/633 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM5 | c.327C>A p.S109R | Missense Mutation (SNP) | VAF 73/627 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM6 | c.1942del p.A648Rfs*65 | Frame Shift Del (DEL) | VAF 88/408 reads (22%) | called by mutect2, varscan2
- HGFAC | c.1238C>A p.S413Y | Missense Mutation (SNP) | VAF 43/531 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.182); called by muse, mutect2
- IGFBP3 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IGKV2D-28 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by mutect2, varscan2
- IRF4 | c.533G>A p.W178* | Nonsense Mutation (SNP) | VAF 51/357 reads (14%) | called by muse, mutect2, varscan2
- KALRN | c.4985G>T p.S1662I | Missense Mutation (SNP) | VAF 70/411 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KCNA5 | c.1632G>T p.Q544H | Missense Mutation (SNP) | VAF 109/362 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNJ4 | c.1192G>T p.A398S | Missense Mutation (SNP) | VAF 106/382 reads (28%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF1A | c.4996G>T p.D1666Y (on ENST00000320389 / NM_001379639.1; = p.D1658Y on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/393 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLHL34 | c.875A>G p.E292G | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- LAMA4 | c.4829C>A p.S1610Y (on ENST00000230538 / NM_001105206.3; = p.S1603Y on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.9202A>T p.S3068C | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- LRP1B | c.7508G>T p.C2503F | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC4C | c.756G>T p.Q252H | Missense Mutation (SNP) | VAF 50/338 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LUZP2 | c.658G>T p.D220Y | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- MAFG | c.142_144del p.E48del | In Frame Del (DEL) | VAF 49/334 reads (15%) | called by pindel, varscan2
- MAP3K7CL | c.55A>T p.K19* | Nonsense Mutation (SNP) | VAF 23/239 reads (10%) | called by muse, mutect2
- MARCHF1 | c.851C>A p.P284H (on ENST00000274056; = p.P267H on NM_017923.4) | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- MATN2 | c.539T>G p.V180G | Missense Mutation (SNP) | VAF 63/390 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- MCTP2 | c.1375G>T p.G459W | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MED15 | c.811C>A p.Q271K | Missense Mutation (SNP) | VAF 650/1418 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- MN1 | c.1682T>G p.M561R | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.203); called by muse, varscan2
- MNDA | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- MSTN | c.410G>T p.C137F | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MTCL1 | c.1954A>T p.I652F (on ENST00000306329 / NM_001378206.1; = p.I292F on NM_015210.4) | Missense Mutation (SNP) | VAF 72/392 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- MUSK | c.685G>T p.V229L | Missense Mutation (SNP) | VAF 49/305 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- MYBPC2 | c.1594T>A p.Y532N | Missense Mutation (SNP) | VAF 42/269 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NID2 | c.2305A>T p.M769L | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPIPB11 | c.1889G>T p.G630V | Missense Mutation (SNP) | VAF 186/1047 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, varscan2
- NPIPB11 | c.1888G>T p.G630W | Missense Mutation (SNP) | VAF 189/1050 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.254); called by muse, varscan2
- NR4A2 | c.865-1G>T p.X289_splice | Splice Site (SNP) | VAF 133/992 reads (13%) | called by muse, mutect2, varscan2
- NUCB2 | c.1106A>G p.Q369R | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- OR2T33 | c.538C>G p.P180A | Missense Mutation (SNP) | VAF 60/771 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2
- OR4C11 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- OR51B2 | c.736G>T p.V246F | Missense Mutation (SNP) | VAF 34/238 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- OR5D14 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 45/369 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OR5H2 | c.146G>T p.G49V | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- OR5T2 | c.540C>A p.Y180* | Nonsense Mutation (SNP) | VAF 26/125 reads (21%) | called by muse, mutect2, varscan2
- OR6B2 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, varscan2
- OR6K6 | c.92G>T p.S31I (on ENST00000368144; = p.S7I on NM_001005184.1) | Missense Mutation (SNP) | VAF 34/282 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ORM1 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 38/177 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPC5 | c.821C>A p.A274E | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PBRM1 | c.2116A>G p.M706V | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PCDH10 | c.1736del p.P579Qfs*48 | Frame Shift Del (DEL) | VAF 23/222 reads (10%) | called by mutect2, pindel, varscan2
- PCDHGB4 | c.587T>G p.L196W | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDILT | c.878T>A p.I293N | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.226); called by muse, mutect2
- PEX2 | c.645G>T p.K215N | Missense Mutation (SNP) | VAF 55/250 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- PIAS2 | c.120G>T p.R40S | Missense Mutation (SNP) | VAF 35/222 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PLA2G5 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PPP1R3A | c.4G>T p.E2* | Nonsense Mutation (SNP) | VAF 20/201 reads (10%) | called by muse, mutect2
- PTPRQ | c.6029A>T p.E2010V (on ENST00000616559; = p.E1968V on NM_001145026.2) | Missense Mutation (SNP) | VAF 73/241 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- RAB11FIP4 | c.925G>T p.G309* | Nonsense Mutation (SNP) | VAF 25/157 reads (16%) | called by muse, mutect2, varscan2
- RAB28 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 28/402 reads (7%) | called by muse, mutect2
- RAD54B | c.2072A>T p.D691V | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RB1CC1 | c.1220C>G p.S407C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- SAMD9 | c.4732A>G p.I1578V | Missense Mutation (SNP) | VAF 53/266 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SCN8A | c.5079C>A p.N1693K | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SHROOM3 | c.3198G>T p.K1066N | Missense Mutation (SNP) | VAF 78/535 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- SLA | c.354G>T p.G118= (on ENST00000338087 / NM_001045556.3; = p.G158= on NM_006748.4) | Splice Region (SNP) | VAF 44/276 reads (16%) | called by muse, varscan2
- SLC23A3 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 142/504 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC26A1 | c.1018C>A p.R340S | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLC6A17 | c.337C>A p.L113I | Missense Mutation (SNP) | VAF 46/437 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SLX4 | c.2433G>T p.R811S | Missense Mutation (SNP) | VAF 77/349 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SORBS2 | c.1772C>A p.A591E | Missense Mutation (SNP) | VAF 90/696 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SORCS1 | c.673G>C p.G225R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- SPATA31A6 | c.1957C>G p.Q653E | Missense Mutation (SNP) | VAF 200/767 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- SPDEF | c.230C>G p.A77G | Missense Mutation (SNP) | VAF 28/237 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPTBN1 | c.7001T>C p.V2334A | Missense Mutation (SNP) | VAF 146/1131 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPTBN2 | c.1514G>T p.R505L | Missense Mutation (SNP) | VAF 39/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SSMEM1 | c.325C>T p.L109F | Missense Mutation (SNP) | VAF 44/290 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- STARD13 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 59/242 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- STEAP3 | c.43G>T p.V15L | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- STK35 | c.1238C>G p.S413C | Missense Mutation (SNP) | VAF 74/350 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- STOX2 | c.614A>T p.D205V | Missense Mutation (SNP) | VAF 83/634 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- STRC | c.419T>A p.L140H | Missense Mutation (SNP) | VAF 67/883 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- STYXL2 | c.2052C>A p.H684Q | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SVIL | c.3734C>A p.P1245H (on ENST00000355867 / NM_021738.3; = p.P819H on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/269 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- SYT16 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 88/476 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- TELO2 | c.933G>T p.T311= | Splice Region (SNP) | VAF 38/186 reads (20%) | called by mutect2, varscan2
- TENM4 | c.5609G>T p.R1870L | Missense Mutation (SNP) | VAF 113/726 reads (16%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TEX13C | c.746C>A p.P249Q | Missense Mutation (SNP) | VAF 93/568 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THRAP3 | c.958A>G p.S320G | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- TIAM2 | c.2636A>G p.D879G | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TJAP1 | c.1025C>T p.P342L (on ENST00000372445 / NM_001146016.1; = p.P332L on NM_080604.3) | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMPRSS15 | c.1952A>T p.K651I | Missense Mutation (SNP) | VAF 27/253 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TNFRSF11B | c.374C>A p.P125H | Missense Mutation (SNP) | VAF 50/558 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.017); called by muse, mutect2
- TRIM49 | c.249G>T p.W83C | Missense Mutation (SNP) | VAF 38/435 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRPA1 | c.1694C>A p.A565E | Missense Mutation (SNP) | VAF 138/561 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- TRPA1 | c.1585A>T p.T529S | Missense Mutation (SNP) | VAF 46/614 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRPM5 | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 60/369 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- TTC30A | c.1370A>C p.H457P | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TTC30B | c.1370A>C p.H457P | Missense Mutation (SNP) | VAF 54/568 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); called by muse, mutect2
- UNC80 | c.1899G>T p.E633D | Missense Mutation (SNP) | VAF 59/304 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- VWA3A | c.3089T>A p.L1030Q | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- VWA5B1 | c.1402G>A p.V468I | Missense Mutation (SNP) | VAF 53/542 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- WTAP | c.751A>T p.T251S | Missense Mutation (SNP) | VAF 60/375 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- XKR3 | c.1017G>C p.Q339H | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- XKRX | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 55/338 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ZFHX4 | c.4733G>T p.S1578I | Missense Mutation (SNP) | VAF 72/370 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZFYVE26 | c.3520C>A p.P1174T | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.812); called by muse, mutect2
- ZNF521 | c.2387T>A p.V796E | Missense Mutation (SNP) | VAF 82/438 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF536 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 44/259 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZNF727 | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ZP4 | c.1595A>T p.K532M | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- ZSCAN2 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 51/351 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, mutect2, varscan2
- A4GNT | c.516C>T p.S172= | Silent (SNP) | VAF 57/551 reads (10%) | called by muse, mutect2, varscan2
- ABCB5 | c.2901C>A p.A967= (on ENST00000404938 / NM_001163941.2; = p.A522= on NM_178559.6) | Silent (SNP) | VAF 13/105 reads (12%) | called by muse, mutect2, varscan2
- AC138647.1 | c.285C>T p.L95= | Silent (SNP) | VAF 34/291 reads (12%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.1443G>C p.L481= | Silent (SNP) | VAF 35/269 reads (13%) | called by muse, mutect2, varscan2
- AFF2 | c.1053C>A p.P351= | Silent (SNP) | VAF 21/178 reads (12%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.3714A>T p.T1238= | Silent (SNP) | VAF 25/236 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.1653A>G p.R551= | Silent (SNP) | VAF 14/133 reads (11%) | catalogued as rs1400686726; called by muse, mutect2, varscan2
- ATF6B | c.510A>T p.P170= | Silent (SNP) | VAF 65/507 reads (13%) | called by muse, mutect2, varscan2
- BPIFA1 | c.84G>T p.L28= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV62825093; called by muse, mutect2, varscan2
- CA4 | c.711G>A p.V237= | Silent (SNP) | VAF 60/405 reads (15%) | called by muse, mutect2, varscan2
- CACNA1E | c.568C>A p.R190= | Silent (SNP) | VAF 32/502 reads (6%) | catalogued as COSV62414168; called by muse, mutect2
- CCDC168 | c.4752C>A p.V1584= | Silent (SNP) | VAF 35/218 reads (16%) | called by muse, mutect2, varscan2
- CDH23 | c.4188C>G p.P1396= | Silent (SNP) | VAF 36/314 reads (11%) | called by muse, mutect2, varscan2
- CDH3 | c.1026G>T p.V342= | Silent (SNP) | VAF 46/462 reads (10%) | called by muse, mutect2
- CFAP100 | c.774C>A p.V258= | Silent (SNP) | VAF 53/235 reads (23%) | catalogued as COSV100729203, COSV61504342; called by muse, mutect2, varscan2
- CHRD | c.798G>C p.G266= | Silent (SNP) | VAF 34/333 reads (10%) | called by muse, mutect2, varscan2
- CHSY3 | c.1200A>T p.A400= | Silent (SNP) | VAF 32/236 reads (14%) | called by muse, mutect2, varscan2
- CLEC3A | c.366C>G p.A122= (on ENST00000651443; = p.A113= on NM_005752.6) | Silent (SNP) | VAF 118/436 reads (27%) | called by muse, mutect2, varscan2
- CLNK | c.534T>A p.P178= | Silent (SNP) | VAF 26/288 reads (9%) | catalogued as rs757569285; called by muse, mutect2
- CPS1 | c.1941C>A p.V647= | Silent (SNP) | VAF 39/266 reads (15%) | called by muse, mutect2, varscan2
- CRYBA2 | c.48C>A p.L16= | Silent (SNP) | VAF 64/324 reads (20%) | called by muse, mutect2, varscan2
- CYP11A1 | c.693G>A p.Q231= | Silent (SNP) | VAF 112/521 reads (21%) | catalogued as COSV99165942; called by muse, mutect2, varscan2
- DAXX | c.1836C>T p.S612= | Silent (SNP) | VAF 52/352 reads (15%) | catalogued as rs764000410; called by muse, mutect2, varscan2
- ESYT1 | c.1983C>G p.A661= | Silent (SNP) | VAF 38/122 reads (31%) | called by muse, mutect2, varscan2
- FAM171B | c.2289C>T p.I763= | Silent (SNP) | VAF 35/208 reads (17%) | called by muse, mutect2, varscan2
- FAM20C | c.804G>A p.T268= | Silent (SNP) | VAF 19/202 reads (9%) | catalogued as rs373718419; called by muse, mutect2, varscan2
- FAT3 | c.4146G>C p.G1382= | Silent (SNP) | VAF 51/292 reads (17%) | called by muse, mutect2, varscan2
- FNDC1 | c.2256C>A p.A752= | Silent (SNP) | VAF 24/178 reads (13%) | called by muse, mutect2, varscan2
- GALC | c.1137C>T p.N379= | Silent (SNP) | VAF 22/377 reads (6%) | called by muse, mutect2
- GALNTL6 | c.234G>A p.E78= | Silent (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- GJB5 | c.267G>A p.L89= | Silent (SNP) | VAF 56/600 reads (9%) | called by muse, mutect2
- HYDIN | c.14715A>G p.L4905= | Silent (SNP) | VAF 28/454 reads (6%) | catalogued as COSV101124954; called by muse, mutect2
- IGHV3-30 | c.270C>G p.S90= | Silent (SNP) | VAF 90/1985 reads (5%) | called by muse, mutect2
- IGKV2D-26 | c.216G>T p.L72= | Silent (SNP) | VAF 73/548 reads (13%) | called by muse, mutect2, varscan2
- IRX4 | c.843C>T p.S281= | Silent (SNP) | VAF 24/277 reads (9%) | called by muse, mutect2
- KCNC2 | c.1194C>A p.T398= | Silent (SNP) | VAF 47/182 reads (26%) | called by muse, mutect2, varscan2
- KIF17 | c.2583G>T p.L861= | Silent (SNP) | VAF 60/476 reads (13%) | called by muse, mutect2, varscan2
- KIF1A | c.2134C>A p.R712= | Silent (SNP) | VAF 28/115 reads (24%) | catalogued as COSV57487522; called by muse, mutect2, varscan2
- KRT35 | c.1023G>T p.L341= | Silent (SNP) | VAF 41/218 reads (19%) | called by muse, mutect2, varscan2
- MAPKBP1 | c.4437A>T p.P1479= (on ENST00000456763 / NM_001128608.2; = p.P1473= on NM_014994.3) | Silent (SNP) | VAF 66/426 reads (15%) | called by muse, mutect2, varscan2
- MCTP2 | c.1374G>T p.L458= | Silent (SNP) | VAF 23/206 reads (11%) | called by muse, mutect2, varscan2
- MFAP3L | c.174C>T p.V58= | Silent (SNP) | VAF 60/556 reads (11%) | called by muse, mutect2, varscan2
- MOG | c.210C>G p.R70= | Silent (SNP) | VAF 49/286 reads (17%) | called by muse, mutect2, varscan2
- MRC1 | c.261T>C p.T87= | Silent (SNP) | VAF 89/988 reads (9%) | called by muse, mutect2
- MROH1 | c.108G>A p.G36= | Silent (SNP) | VAF 40/319 reads (13%) | called by muse, mutect2, varscan2
- MUC12 | c.15471G>T p.L5157= (on ENST00000379442; = p.L5014= on NM_001164462.1) | Silent (SNP) | VAF 22/263 reads (8%) | called by muse, mutect2
- MYH13 | c.1779C>G p.A593= | Silent (SNP) | VAF 62/347 reads (18%) | catalogued as rs761135768; called by muse, mutect2, varscan2
- MYO15B | c.4005C>T p.F1335= | Silent (SNP) | VAF 35/232 reads (15%) | called by muse, mutect2, varscan2
- NBPF3 | c.9G>T p.L3= | Silent (SNP) | VAF 26/129 reads (20%) | called by muse, mutect2, varscan2
- NCK2 | c.591G>T p.L197= | Silent (SNP) | VAF 26/205 reads (13%) | called by muse, mutect2, varscan2
- NDN | c.498G>T p.A166= | Silent (SNP) | VAF 69/428 reads (16%) | catalogued as rs754515050; called by muse, mutect2, varscan2
- NOD1 | c.865C>T p.L289= | Silent (SNP) | VAF 22/386 reads (6%) | called by muse, mutect2
- NUP42 | c.996G>T p.V332= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as COSV51731293; called by muse, mutect2, varscan2
- OR51I2 | c.441T>G p.G147= | Silent (SNP) | VAF 40/298 reads (13%) | called by muse, mutect2, varscan2
- OR52B4 | c.156C>T p.L52= | Silent (SNP) | VAF 58/358 reads (16%) | called by muse, mutect2, varscan2
- OR5J2 | c.657C>A p.I219= | Silent (SNP) | VAF 48/369 reads (13%) | catalogued as rs1248112021, COSV100399319; called by muse, mutect2, varscan2
- PDHA2 | c.561C>A p.I187= | Silent (SNP) | VAF 39/323 reads (12%) | catalogued as COSV54781381; called by muse, mutect2, varscan2
- PNPLA8 | c.897A>G p.Q299= | Silent (SNP) | VAF 17/227 reads (7%) | catalogued as rs1440639745; called by muse, mutect2
- POLN | c.339T>A p.T113= | Silent (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- PON3 | c.801G>T p.V267= | Silent (SNP) | VAF 71/479 reads (15%) | catalogued as COSV99672320; called by muse, mutect2, varscan2
- POTEF | c.2157C>G p.A719= | Silent (SNP) | VAF 112/1094 reads (10%) | called by muse, mutect2
- PPEF2 | c.2211A>G p.P737= | Silent (SNP) | VAF 55/305 reads (18%) | catalogued as rs1445821970; called by muse, mutect2, varscan2
- PPIP5K2 | c.2991G>T p.V997= | Silent (SNP) | VAF 40/154 reads (26%) | called by muse, mutect2, varscan2
- PTDSS2 | c.597G>T p.A199= | Silent (SNP) | VAF 45/381 reads (12%) | called by muse, mutect2, varscan2
- PTPRT | c.3096G>A p.Q1032= | Silent (SNP) | VAF 42/253 reads (17%) | catalogued as COSV62023736; called by muse, mutect2, varscan2
- QPRT | c.414G>A p.R138= | Silent (SNP) | VAF 30/366 reads (8%) | catalogued as rs1308639569; called by muse, mutect2
- RBBP8 | c.2310A>G p.K770= | Silent (SNP) | VAF 113/593 reads (19%) | called by muse, mutect2, varscan2
- RYR1 | c.6318C>A p.A2106= | Silent (SNP) | VAF 81/349 reads (23%) | catalogued as rs769443054; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SATB2 | c.2001G>T p.R667= | Silent (SNP) | VAF 146/946 reads (15%) | called by muse, mutect2, varscan2
- SDR39U1 | c.636C>T p.H212= | Silent (SNP) | VAF 73/333 reads (22%) | catalogued as rs373640189; called by muse, mutect2, varscan2
- SEL1L2 | c.1989T>A p.I663= | Silent (SNP) | VAF 21/247 reads (9%) | called by muse, mutect2
- SHC4 | c.492G>T p.P164= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- SLA | c.438G>T p.P146= (on ENST00000338087 / NM_001045556.3; = p.P186= on NM_006748.4) | Silent (SNP) | VAF 72/478 reads (15%) | called by muse, varscan2
- SPSB4 | c.792G>A p.Q264= | Silent (SNP) | VAF 18/518 reads (3%) | called by muse, mutect2
- TBRG4 | c.1752G>T p.L584= | Silent (SNP) | VAF 33/323 reads (10%) | called by muse, mutect2, varscan2
- TECPR2 | c.3969C>T p.T1323= | Silent (SNP) | VAF 45/224 reads (20%) | catalogued as rs562186436; called by muse, mutect2, varscan2
- TFAP2C | c.870G>T p.P290= | Silent (SNP) | VAF 79/382 reads (21%) | catalogued as COSV99571883; called by muse, mutect2, varscan2
- TLR3 | c.1644C>T p.H548= | Silent (SNP) | VAF 19/146 reads (13%) | catalogued as rs147873871; called by muse, mutect2, varscan2
- TMEM132E | c.2223G>C p.G741= (on ENST00000321639; = p.G831= on NM_001304438.2) | Silent (SNP) | VAF 17/124 reads (14%) | called by muse, mutect2, varscan2
- TTLL10 | c.1713C>T p.D571= | Silent (SNP) | VAF 25/155 reads (16%) | called by muse, mutect2, varscan2
- UHRF1BP1 | c.108G>T p.L36= | Silent (SNP) | VAF 23/191 reads (12%) | called by muse, mutect2, varscan2
- USP32 | c.720T>C p.F240= | Silent (SNP) | VAF 14/147 reads (10%) | called by muse, mutect2
- WASHC2A | c.2523G>A p.Q841= | Silent (SNP) | VAF 24/338 reads (7%) | called by muse, mutect2
- YIF1A | c.48C>T p.A16= | Silent (SNP) | VAF 80/395 reads (20%) | called by muse, mutect2, varscan2
- YTHDF3 | c.930A>T p.P310= | Silent (SNP) | VAF 68/510 reads (13%) | called by muse, mutect2, varscan2
- ZG16 | c.354G>A p.L118= | Silent (SNP) | VAF 38/528 reads (7%) | catalogued as rs1369433308; called by muse, mutect2
- AC005008.1 | chr7:81187809 G>T | 5'Flank (SNP) | VAF 27/128 reads (21%) | called by muse, mutect2, varscan2
- AC009533.1 | n.1253del | RNA (DEL) | VAF 234/1121 reads (21%) | called by mutect2, pindel, varscan2
- AC133552.2 | n.457G>C | RNA (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- AGMO | c.1263+59044del | Intron (DEL) | VAF 14/163 reads (9%) | called by mutect2, pindel*
- AL353804.7 | chrX:73847135 G>T | 5'Flank (SNP) | VAF 31/245 reads (13%) | called by muse, mutect2, varscan2
- ANXA8 | c.*19C>A | 3'UTR (SNP) | VAF 46/838 reads (5%) | called by muse, mutect2
- BET1-AS1 | n.225+6322G>A | Intron (SNP) | VAF 10/59 reads (17%) | called by muse, varscan2
- CACNA1C | c.2853+207G>T | Intron (SNP) | VAF 66/268 reads (25%) | called by muse, mutect2, varscan2
- CDH13 | c.45+78015G>T | Intron (SNP) | VAF 31/223 reads (14%) | called by muse, mutect2, varscan2
- COL6A1 | c.1741-57C>T | Intron (SNP) | VAF 50/278 reads (18%) | catalogued as rs1037701209; called by muse, mutect2, varscan2
- CROCC2 | c.4558-2797G>T | Intron (SNP) | VAF 28/211 reads (13%) | called by muse, mutect2, varscan2
- CSF1R | c.889+45G>T | Intron (SNP) | VAF 113/484 reads (23%) | catalogued as rs1419556559; called by muse, mutect2, varscan2
- CYFIP2 | c.3282+1001A>T | Intron (SNP) | VAF 62/317 reads (20%) | called by muse, mutect2, varscan2
- DACH2 | c.488+35130C>A | Intron (SNP) | VAF 6/50 reads (12%) | catalogued as COSV64168667; called by muse, mutect2
- ERVV-1 | chr19:53010141 C>A | 5'Flank (SNP) | VAF 61/327 reads (19%) | called by muse, mutect2, varscan2
- EYS | c.1767-6605C>A | Intron (SNP) | VAF 39/698 reads (6%) | called by muse, mutect2
- FAM138C | n.314G>T | RNA (SNP) | VAF 27/154 reads (18%) | called by mutect2, varscan2
- GOLGA6L3 | n.458C>A | RNA (SNP) | VAF 44/623 reads (7%) | catalogued as rs1261212973; called by muse, mutect2, varscan2
- KLHL22 | c.-34+2598C>A | Intron (SNP) | VAF 68/572 reads (12%) | called by muse, mutect2, varscan2
- KYAT1 | c.1122+20G>A | Intron (SNP) | VAF 88/435 reads (20%) | called by muse, mutect2, varscan2
- LINC02312 | n.605C>A | RNA (SNP) | VAF 34/495 reads (7%) | called by muse, mutect2
- LRRC53 | c.-4C>A | 5'UTR (SNP) | VAF 20/141 reads (14%) | catalogued as COSV53953384; called by muse, mutect2, varscan2
- MCF2 | chrX:139645568 C>A | 5'Flank (SNP) | VAF 24/151 reads (16%) | catalogued as COSV58480088; called by muse, mutect2, varscan2
- MTNR1A | c.*27G>C | 3'UTR (SNP) | VAF 28/280 reads (10%) | called by muse, mutect2, varscan2
- MYOCD | c.2059-1544C>A | Intron (SNP) | VAF 41/198 reads (21%) | called by muse, mutect2, varscan2
- NGEF | c.829-10872C>A | Intron (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- OR2W5 | n.441C>A | RNA (SNP) | VAF 77/631 reads (12%) | called by muse, mutect2, varscan2
- OR6W1P | n.911del | RNA (DEL) | VAF 20/104 reads (19%) | called by mutect2, pindel, varscan2
- OR6W1P | n.179C>A | RNA (SNP) | VAF 40/293 reads (14%) | called by muse, mutect2, varscan2
- PIGK | c.987-7214C>G | Intron (SNP) | VAF 22/348 reads (6%) | called by muse, mutect2
- POPDC2 | c.1010-829G>A | Intron (SNP) | VAF 34/425 reads (8%) | called by muse, mutect2
- PRKCZ | c.975-184G>T | Intron (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
- RAMP2 | chr17:42759836 T>G | 5'Flank (SNP) | VAF 60/498 reads (12%) | called by muse, mutect2, varscan2
- RD3 | c.*20C>A | 3'UTR (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
- SHOC2 | c.-235+17150G>T | Intron (SNP) | VAF 129/839 reads (15%) | called by muse, mutect2, varscan2
- SIRT3 | c.969+298A>T | Intron (SNP) | VAF 16/160 reads (10%) | called by muse, varscan2
- SLC6A10P | n.3196T>A | RNA (SNP) | VAF 32/478 reads (7%) | called by muse, mutect2
- SNX5 | c.-135G>T | 5'UTR (SNP) | VAF 21/173 reads (12%) | catalogued as rs372501690; called by muse, mutect2, varscan2
- SPATA31C1 | n.556A>T | RNA (SNP) | VAF 93/645 reads (14%) | called by muse, mutect2, varscan2
- SPEG | c.2882-1073C>G | Intron (SNP) | VAF 38/231 reads (16%) | called by muse, mutect2, varscan2
- SPEG | c.2882-1072G>A | Intron (SNP) | VAF 37/224 reads (17%) | catalogued as rs1184753245, COSV100403168; called by muse, mutect2, varscan2
- SSPOP | n.14523G>T | RNA (SNP) | VAF 40/304 reads (13%) | called by muse, mutect2, varscan2
- TADA1 | c.-7C>A | 5'UTR (SNP) | VAF 24/262 reads (9%) | called by muse, mutect2
- TBC1D22A | c.1015+1234C>T | Intron (SNP) | VAF 31/204 reads (15%) | called by muse, mutect2, varscan2
- TBC1D3P2 | n.411G>T | RNA (SNP) | VAF 79/494 reads (16%) | called by muse, mutect2, varscan2
- TMPRSS11BNL | n.418T>C | RNA (SNP) | VAF 5/68 reads (7%) | catalogued as rs1000507742; called by muse, mutect2
- TSHR | c.692+97G>A | Intron (SNP) | VAF 35/235 reads (15%) | called by muse, mutect2, varscan2
- VAV3 | c.1706-15T>C | Intron (SNP) | VAF 33/240 reads (14%) | called by muse, mutect2, varscan2
- VPS28 | c.549-38G>T | Intron (SNP) | VAF 31/246 reads (13%) | called by muse, mutect2, varscan2
- ZAP70 | c.837+34G>T | Intron (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- ZNF487 | c.*1192C>T | 3'UTR (SNP) | VAF 32/164 reads (20%) | catalogued as rs893271614; called by muse, varscan2
